Somatic mutation profile of tumor specimen TARGET-30-PATMJV-09A (aliquot TARGET-30-PATMJV-09A-01D) from TARGET case TARGET-30-PATMJV, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.9 years (4,350 days).
Specimen TARGET-30-PATMJV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e75c079-2046-4db4-9c5f-cfb6f381eb97.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATMJV-10A (Blood Derived Normal), aliquot TARGET-30-PATMJV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/516c25cf-1c14-4818-a4cb-0751b4c7d2a3

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 1, 5'Flank 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GSE1 | c.1795C>T p.R599W | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138340924; called by muse, mutect2, varscan2
- LAMB2 | c.780C>T p.L260= | Silent (SNP) | VAF 48/54 reads (89%) | catalogued as rs1560076637, COSV59731233; called by muse, mutect2, varscan2
- TRPS1 | chr8:115668797 G>C | 5'Flank (SNP) | VAF 25/71 reads (35%) | catalogued as rs1341578697, COSV55228249; called by muse, mutect2, varscan2
